Somatic mutation profile of tumor specimen TCGA-BS-A0T9-01A (aliquot TCGA-BS-A0T9-01A-11D-A12J-09) from TCGA case TCGA-BS-A0T9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 39.0 years (14,253 days).
Specimen TCGA-BS-A0T9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c0c889a-04b1-4802-9160-4e7d454ced4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0T9-10C (Blood Derived Normal), aliquot TCGA-BS-A0T9-10C-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de2ad78e-ed48-4de9-bdac-02eaf10c0d6a

The open-access MAF lists 66 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 44, Silent 11, Frame Shift Ins 3, In Frame Del 3, Nonsense Mutation 3, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 32/148 reads (22%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTCF | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 36/230 reads (16%) | hotspot (GDC flag); catalogued as rs769948988, COSV50461776; called by muse, mutect2, varscan2
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 56/133 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1398_1409del p.L466_Y470delinsF (on ENST00000521381 / NM_181523.3; = p.L196_Y200delinsF on NM_181504.4) | In Frame Del (DEL) | VAF 47/156 reads (30%) | hotspot (GDC flag); catalogued as COSV57134862; called by mutect2, pindel, varscan2
- AGBL1 | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767364604, COSV101224391, COSV66858368; called by muse, mutect2, varscan2
- ALDH1L2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs541905823, COSV51554406; called by mutect2, varscan2
- ANAPC1 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 138/368 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs375588038; called by muse, mutect2, varscan2
- CARMIL3 | c.2190G>A p.A730= | Splice Region (SNP) | VAF 12/76 reads (16%) | catalogued as rs755686616, COSV100549013, COSV57727570; called by muse, mutect2, varscan2
- CCDC142 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs199921112, COSV51778987; called by muse, mutect2, varscan2
- CEP43 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 78/409 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV62761266; called by muse, mutect2, varscan2
- CHD4 | c.2398C>T p.R800C (on ENST00000357008 / NM_001363606.2; = p.R813C on NM_001273.5) | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894214; called by muse, mutect2, varscan2
- COL11A1 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62190230; called by muse, mutect2, varscan2
- CSMD3 | c.533G>T p.C178F | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV52252177; called by muse, mutect2, varscan2
- CTCF | c.1549C>T p.H517Y | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50481810, COSV50489718; called by muse, mutect2, varscan2
- CUBN | c.5323C>T p.R1775W | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1276708; called by muse, mutect2, varscan2
- CXCR2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as rs780840157, COSV59280944; called by muse, mutect2, varscan2
- CYP4F11 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs369765939; called by muse, mutect2, varscan2
- DNAJC13 | c.3899A>G p.D1300G | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV53454680; called by muse, mutect2, varscan2
- EHBP1L1 | c.4418C>T p.S1473L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1339483877, COSV58574171; called by muse, mutect2, varscan2
- EYS | c.82T>A p.L28M | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.024); catalogued as COSV60993841; called by muse, mutect2, varscan2
- F8 | c.6058C>T p.L2020F | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV64276444; called by muse, mutect2, varscan2
- FADD | c.410T>A p.L137Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57229551; called by muse, mutect2, varscan2
- FMR1NB | c.714G>C p.K238N | Missense Mutation (SNP) | VAF 118/532 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.15); catalogued as COSV65072618; called by muse, mutect2, varscan2
- GPHA2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs755701259, COSV51211536; called by mutect2, varscan2
- GRID2 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56235142; called by muse, mutect2, varscan2
- IL31RA | c.1608C>A p.N536K | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV51681647, COSV51683433; called by muse, mutect2, varscan2
- IPP | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs370892993; called by muse, mutect2, varscan2
- LMTK3 | c.3044C>T p.T1015M | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV54315230; called by muse, mutect2, varscan2
- LRCH2 | c.1402A>T p.K468* | Nonsense Mutation (SNP) | VAF 79/650 reads (12%) | catalogued as COSV57755581; called by muse, mutect2, varscan2
- LRRC24 | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.714); catalogued as COSV52881039; called by muse, mutect2, varscan2
- MAX | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs776978293, COSV52416114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP3 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV55406116, COSV55407181; called by muse, mutect2, varscan2
- MYO3A | c.1945G>T p.A649S | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56333040; called by muse, mutect2, varscan2
- OR10X1 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63767705; called by muse, mutect2, varscan2
- OR2T35 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1460438089, COSV58086755; called by muse, mutect2, varscan2
- PDK3 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64793916; called by muse, mutect2
- PRMT1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV54919034, COSV54919285; called by muse, mutect2, varscan2
- PTEN | c.170del p.L57Wfs*42 | Frame Shift Del (DEL) | VAF 91/231 reads (39%) | catalogued as COSV64290332; called by mutect2, pindel, varscan2
- PTPRB | c.5137G>A p.V1713M | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1163632246, COSV54246657; called by muse, mutect2, varscan2
- PTPRD | c.1536G>T p.Q512H | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV100644148, COSV61965957; called by muse, mutect2, varscan2
- RABL3 | c.322C>G p.R108G | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56336671, COSV56337065; called by muse, mutect2, varscan2
- SLC5A3 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62971768; called by muse, mutect2, varscan2
- SMS | c.911A>T p.K304I | Missense Mutation (SNP) | VAF 75/401 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV65114786; called by muse, mutect2, varscan2
- TASOR2 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 59/484 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs1344956127, COSV60168624; called by muse, mutect2, varscan2
- TDRD5 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as COSV54246983; called by muse, mutect2, varscan2
- THADA | c.5416C>A p.L1806M | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57688791; called by muse, mutect2, varscan2
- TNFAIP6 | c.258G>C p.W86C | Missense Mutation (SNP) | VAF 75/392 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54641721; called by muse, mutect2, varscan2
- TNKS2 | c.3242G>T p.C1081F | Missense Mutation (SNP) | VAF 150/342 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65416199; called by muse, mutect2, varscan2
- TRPM6 | c.5883C>G p.N1961K | Missense Mutation (SNP) | VAF 75/282 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62517147; called by muse, mutect2, varscan2
- ZNF471 | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57292540; called by muse, mutect2, varscan2
- ZNF483 | c.934A>T p.K312* | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | catalogued as COSV58516497; called by muse, mutect2, varscan2
- CHD4 | c.3133dup p.M1045Nfs*6 (on ENST00000357008 / NM_001363606.2; = p.M1058Nfs*6 on NM_001273.5) | Frame Shift Ins (INS) | VAF 32/179 reads (18%) | called by mutect2, pindel, varscan2
- FAM47C | c.943_957del p.V315_R319del | In Frame Del (DEL) | VAF 24/184 reads (13%) | called by mutect2, pindel
- OGT | c.227_262del p.H76_L87del | In Frame Del (DEL) | VAF 54/310 reads (17%) | called by mutect2, pindel, varscan2
- TRIM75P | c.942dup p.R315Tfs*40 | Frame Shift Ins (INS) | VAF 20/191 reads (10%) | called by mutect2, pindel, varscan2
- CAPN15 | c.2199G>A p.L733= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV54836833; called by muse, mutect2, varscan2
- CD5L | c.171C>T p.D57= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as rs141811796; called by muse, mutect2, varscan2
- CYP39A1 | c.918G>T p.V306= | Silent (SNP) | VAF 89/431 reads (21%) | catalogued as COSV51497640; called by muse, mutect2, varscan2
- DIAPH3 | c.1782A>C p.P594= (on ENST00000400324 / NM_001042517.2; = p.P331= on NM_030932.3) | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV57375425; called by muse, varscan2
- F10 | c.468C>A p.T156= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV65021447; called by muse, mutect2, varscan2
- FADS6 | c.693C>T p.G231= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs760589322, COSV59603236; called by muse, mutect2, varscan2
- GNAQ | c.612C>T p.V204= | Silent (SNP) | VAF 50/236 reads (21%) | catalogued as rs780431354, COSV54119979; called by muse, mutect2, varscan2
- INTS1 | c.6357C>T p.A2119= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs187219281; called by muse, mutect2, varscan2
- NPAP1 | c.885G>A p.P295= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV61509195; called by muse, mutect2, varscan2
- OR2L3 | c.27T>A p.T9= | Silent (SNP) | VAF 109/579 reads (19%) | catalogued as COSV63455839; called by muse, mutect2, varscan2
- TUB | c.1269C>T p.I423= (on ENST00000299506 / NM_177972.3; = p.I478= on NM_003320.4) | Silent (SNP) | VAF 42/175 reads (24%) | catalogued as rs61733059, COSV55109129; called by muse, mutect2, varscan2
